Somatic mutation profile of tumor specimen ALCH-B2OM-TTP1-A (aliquot ALCH-B2OM-TTP1-A-1-0-D-A77Z-36) from ALCHEMIST case ALCH-B2OM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.8 years (26,235 days).
Specimen ALCH-B2OM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 333bf57a-51f3-4211-a39b-7eb2bf9bf7f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2OM-NB1-A (Blood Derived Normal), aliquot ALCH-B2OM-NB1-A-1-0-D-A77Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed6313f7-d8ec-413a-adb6-67453dcc0f50

The open-access MAF lists 122 somatic variants for this specimen: 88 protein-altering or splice-affecting, 23 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 23, Intron 7, Nonsense Mutation 7, 3'Flank 1, Splice Region 1, Frame Shift Del 1, 3'UTR 1, Splice Site 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 35/185 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs121913238, COSV55502066, COSV55502677; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTOR | c.5395G>A p.E1799K | Missense Mutation (SNP) | VAF 25/225 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as rs863225264, CM156279, COSV63869964; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- CD300LD | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 19/269 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs200915238; called by muse, mutect2
- CDH10 | c.2123C>A p.T708K | Missense Mutation (SNP) | VAF 46/531 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.339); catalogued as COSV52583310; called by muse, mutect2
- COL3A1 | c.951A>G p.A317= | Splice Region (SNP) | VAF 47/461 reads (10%) | catalogued as CD972147; called by muse, mutect2, varscan2
- DACT1 | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 37/401 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV60019815; called by muse, mutect2
- F8 | c.5725T>C p.Y1909H | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1408146517; called by muse, mutect2
- FOXB2 | c.819G>C p.E273D | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs760085688, COSV65024130; called by muse, mutect2, varscan2
- FOXD4L3 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 132/750 reads (18%) | catalogued as COSV100731039; called by muse, mutect2, varscan2
- FSTL5 | c.2062G>A p.G688R | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs777907050; called by muse, mutect2, varscan2
- FYB1 | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 27/462 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs750204135; called by muse, mutect2
- GPR26 | c.361C>G p.R121G | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV52936129; called by muse, mutect2
- HECW2 | c.770A>T p.D257V | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53661245; called by muse, mutect2, varscan2
- IGDCC3 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs773270534; called by muse, mutect2, varscan2
- ITIH6 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs148051323; called by muse, mutect2, varscan2
- KCNA5 | c.1408G>T p.A470S | Missense Mutation (SNP) | VAF 83/388 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.575); catalogued as COSV52909446, COSV99363482; called by muse, mutect2, varscan2
- LTF | c.1978C>T p.L660F | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148227142; called by muse, mutect2, varscan2
- MCF2L | c.74A>G p.N25S | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs752745702; called by muse, mutect2
- MIDEAS | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.353); catalogued as rs777161811; called by muse, mutect2, varscan2
- MMRN1 | c.167C>A p.P56Q | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.368); catalogued as COSV99307223; called by muse, mutect2, varscan2
- NCAM1 | c.2467G>A p.V823I (on ENST00000316851 / NM_181351.5; = p.V813I on NM_000615.7) | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as rs1555126330; called by muse, mutect2
- NES | c.1660C>G p.Q554E | Missense Mutation (SNP) | VAF 19/231 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs761172336; called by muse, mutect2
- OR7E24 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 49/402 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as COSV71702261; called by muse, mutect2, varscan2
- OTOF | c.1313C>A p.A438D | Missense Mutation (SNP) | VAF 34/277 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99717521; called by muse, mutect2, varscan2
- OTOGL | c.5146G>T p.E1716* (on ENST00000547103; = p.E1707* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 54/263 reads (21%) | catalogued as rs1414788054, COSV100087311; called by muse, mutect2, varscan2
- PCDHAC1 | c.166C>A p.R56S | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53872551; called by muse, mutect2
- RTTN | c.557A>G p.H186R | Missense Mutation (SNP) | VAF 34/325 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771590818; called by muse, mutect2, varscan2
- SATL1 | c.70C>G p.P24A (on ENST00000395409; = p.P211A on NM_001012980.2) | Missense Mutation (SNP) | VAF 32/628 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.112); catalogued as COSV100260714; called by muse, mutect2
- SMARCA4 | c.3306C>G p.F1102L | Missense Mutation (SNP) | VAF 52/464 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60786798, COSV60803618; called by muse, mutect2, varscan2
- STXBP5L | c.1810A>T p.K604* | Nonsense Mutation (SNP) | VAF 18/151 reads (12%) | catalogued as COSV56507975; called by muse, mutect2, varscan2
- SYNE2 | c.879G>T p.E293D | Missense Mutation (SNP) | VAF 40/554 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV58360947; called by muse, mutect2
- TKTL2 | c.636G>T p.W212C | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1345995322; called by muse, mutect2
- VEGFA | c.644C>T p.A215V (on ENST00000523873 / NM_001171623.1; = p.A378V on NM_003376.6) | Missense Mutation (SNP) | VAF 53/558 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as rs866329410; called by muse, mutect2
- VIRMA | c.3107C>T p.A1036V | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0.01); catalogued as rs773268386; called by muse, mutect2, varscan2
- VPS41 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 27/269 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs377345756; called by muse, mutect2, varscan2
- ZNF425 | c.2213A>T p.K738M | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as COSV65202024; called by muse, mutect2, varscan2
- ADAM22 | c.1564C>A p.Q522K | Missense Mutation (SNP) | VAF 12/199 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.172); called by muse, mutect2
- ADCY5 | c.1243A>T p.I415F | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- AFF2 | c.3709C>A p.Q1237K | Missense Mutation (SNP) | VAF 28/448 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- AHNAK | c.4286G>T p.G1429V | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ANK2 | c.11031A>C p.E3677D | Missense Mutation (SNP) | VAF 32/500 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2
- AP3B2 | c.3057G>C p.Q1019H (on ENST00000261722; = p.Q1013H on NM_004644.5) | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2
- ARHGAP35 | c.3988G>T p.D1330Y | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); called by muse, mutect2
- ARMC3 | c.2548G>A p.D850N | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CELSR3 | c.4180C>T p.L1394F | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CENPW | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 32/413 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.736); called by muse, mutect2
- COL18A1 | c.3736C>A p.L1246I (on ENST00000359759 / NM_130444.3; = p.L1011I on NM_030582.4) | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.059); called by muse, mutect2
- COPB2 | c.1423G>C p.E475Q | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- CYP2A6 | c.703C>G p.Q235E | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- DCAF4L2 | c.472C>A p.L158M | Missense Mutation (SNP) | VAF 18/289 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.878); called by muse, mutect2
- ELP5 | c.888C>G p.F296L | Missense Mutation (SNP) | VAF 21/307 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.046); called by muse, mutect2
- ENAH | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 74/392 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ENAH | c.1183G>T p.A395S | Missense Mutation (SNP) | VAF 74/394 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- EOMES | c.653C>A p.A218E | Missense Mutation (SNP) | VAF 31/245 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- FRYL | c.4286A>G p.Y1429C | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- GPC3 | c.231G>T p.M77I | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- GRIN2B | c.3713C>A p.A1238E | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- HIRIP3 | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 40/335 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- HNF1A | c.1808C>T p.S603F | Missense Mutation (SNP) | VAF 124/553 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- HR | c.3333G>T p.Q1111H | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITGB1 | c.1340C>G p.P447R | Missense Mutation (SNP) | VAF 37/445 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ITIH6 | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- KIF20B | c.3994C>T p.Q1332* (on ENST00000371728 / NM_001284259.2; = p.Q1292* on NM_016195.4) | Nonsense Mutation (SNP) | VAF 11/174 reads (6%) | called by muse, mutect2
- LMBR1L | c.988G>T p.A330S | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MRPS33 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 30/249 reads (12%) | called by muse, mutect2, varscan2
- MUC17 | c.6811A>C p.T2271P | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.029); called by muse, mutect2
- MUC5B | c.9204del p.I3069Sfs*41 | Frame Shift Del (DEL) | VAF 27/270 reads (10%) | called by mutect2, varscan2
- NEXMIF | c.2965C>G p.R989G | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2
- NUP98 | c.1010C>T p.T337I | Missense Mutation (SNP) | VAF 36/368 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, mutect2
- OCA2 | c.717T>A p.S239R | Missense Mutation (SNP) | VAF 30/418 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.052); called by muse, mutect2
- OGFOD1 | c.612G>A p.W204* | Nonsense Mutation (SNP) | VAF 26/352 reads (7%) | called by muse, mutect2
- OR8U1 | c.823T>A p.S275T | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- PCDHB12 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 27/331 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.364); called by muse, mutect2
- PDE6C | c.406T>C p.F136L | Missense Mutation (SNP) | VAF 28/383 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.088); called by muse, mutect2
- PEG3 | c.3833A>G p.E1278G | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- POM121L2 | c.2747C>G p.S916C | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); called by muse, mutect2
- POU2F1 | c.1139G>C p.R380T (on ENST00000541643 / NM_001365848.1; = p.R403T on NM_002697.4) | Missense Mutation (SNP) | VAF 32/434 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- POU6F2 | c.1256C>A p.S419* | Nonsense Mutation (SNP) | VAF 18/166 reads (11%) | called by muse, mutect2
- PRCC | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PSG9 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 61/337 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR2 | c.6590G>T p.C2197F | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPATA19 | c.*9+2T>A | Splice Site (SNP) | VAF 22/206 reads (11%) | called by muse, mutect2, varscan2
- SRP72 | c.1809G>C p.Q603H | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- TEX15 | c.548A>G p.Q183R (on ENST00000256246; = p.Q566R on NM_001350162.2) | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.058); called by muse, mutect2
- TFCP2 | c.839G>T p.W280L | Missense Mutation (SNP) | VAF 55/366 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- TKTL2 | c.635G>T p.W212L | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2
- TSSC4 | c.262A>T p.T88S | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ZNF382 | c.805G>C p.A269P | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2
- BCHE | c.1620G>A p.T540= | Silent (SNP) | VAF 30/280 reads (11%) | catalogued as rs774356916, COSV52256999; called by muse, mutect2, varscan2
- CENATAC | c.423A>G p.E141= | Silent (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- CHID1 | c.24C>T p.L8= | Silent (SNP) | VAF 36/370 reads (10%) | called by muse, mutect2
- FDPS | c.270C>T p.I90= | Silent (SNP) | VAF 32/533 reads (6%) | catalogued as rs757869821; called by muse, mutect2
- GATA6 | c.543G>T p.A181= | Silent (SNP) | VAF 18/195 reads (9%) | called by muse, mutect2
- GLE1 | c.1740C>T p.I580= | Silent (SNP) | VAF 74/404 reads (18%) | catalogued as rs865801020; called by muse, mutect2, varscan2
- GLG1 | c.147C>T p.F49= | Silent (SNP) | VAF 32/368 reads (9%) | catalogued as rs753121526; called by muse, mutect2
- IGSF3 | c.2724G>T p.V908= (on ENST00000369486 / NM_001007237.3; = p.V928= on NM_001542.4) | Silent (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- KRAS | c.180T>A p.G60= | Silent (SNP) | VAF 35/181 reads (19%) | catalogued as rs397517037, COSV55499291, COSV55523567, COSV99782811; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOS3 | c.1740G>A p.P580= | Silent (SNP) | VAF 14/180 reads (8%) | catalogued as rs761397169; called by muse, mutect2
- NOX1 | c.1578G>T p.V526= | Silent (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2
- OPA3 | c.315G>A p.Q105= | Silent (SNP) | VAF 25/216 reads (12%) | called by muse, mutect2, varscan2
- OR2F2 | c.570G>A p.V190= | Silent (SNP) | VAF 16/177 reads (9%) | catalogued as rs1443500658, COSV68832967; called by muse, mutect2
- POTEI | c.171C>A p.L57= | Silent (SNP) | VAF 41/327 reads (13%) | called by muse, mutect2, varscan2
- PSME1 | c.693G>A p.L231= | Silent (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- PTPN9 | c.276C>A p.L92= | Silent (SNP) | VAF 16/209 reads (8%) | called by muse, mutect2
- RTL3 | c.99C>A p.L33= | Silent (SNP) | VAF 32/301 reads (11%) | catalogued as COSV58184264; called by muse, mutect2, varscan2
- SHANK3 | c.1206C>G p.L402= | Silent (SNP) | VAF 20/187 reads (11%) | called by muse, mutect2, varscan2
- SLC27A4 | c.1392C>G p.L464= | Silent (SNP) | VAF 22/190 reads (12%) | called by muse, mutect2, varscan2
- SULF2 | c.768G>A p.P256= | Silent (SNP) | VAF 16/151 reads (11%) | catalogued as rs201684871, COSV100736945, COSV63414476; called by muse, mutect2, varscan2
- TOM1L2 | c.783C>G p.L261= (on ENST00000379504 / NM_001350333.2; = p.L211= on NM_001033551.3) | Silent (SNP) | VAF 16/118 reads (14%) | called by muse, mutect2, varscan2
- VNN1 | c.375C>T p.S125= | Silent (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- ZFR2 | c.66G>A p.P22= | Silent (SNP) | VAF 24/258 reads (9%) | catalogued as COSV53597816; called by muse, mutect2, varscan2
- AKR1D1 | c.690-128G>T | Intron (SNP) | VAF 22/338 reads (7%) | called by muse, mutect2
- CELF3 | c.773-32C>G | Intron (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- DDX39B | c.-3+262C>G | Intron (SNP) | VAF 22/224 reads (10%) | called by muse, mutect2
- HTR3A | c.*426T>A | 3'UTR (SNP) | VAF 63/430 reads (15%) | called by muse, mutect2, varscan2
- KPNA4 | c.1032+409G>A | Intron (SNP) | VAF 38/457 reads (8%) | called by muse, mutect2
- NDUFA13 | chr19:19515991 T>C | 5'Flank (SNP) | VAF 11/86 reads (13%) | catalogued as rs756735532; called by muse, mutect2
- NDUFV2 | c.-1C>T | 5'UTR (SNP) | VAF 21/201 reads (10%) | catalogued as rs752827701; called by muse, mutect2, varscan2
- PRKACB | c.47-14809G>A | Intron (SNP) | VAF 9/111 reads (8%) | catalogued as rs369513745; called by muse, mutect2
- SLC44A5 | chr1:75203811 A>G | 3'Flank (SNP) | VAF 12/166 reads (7%) | called by muse, mutect2
- UFD1 | c.850-12C>G | Intron (SNP) | VAF 26/223 reads (12%) | called by muse, mutect2, varscan2
- ZSCAN32 | c.915-133G>A | Intron (SNP) | VAF 36/317 reads (11%) | called by muse, mutect2, varscan2
